Somatic mutation profile of tumor specimen 41d0619e-b299-42e2-ac32-29e784 (aliquot 41d0619e-b299-42e2-ac32-29e784_D6_1) from CPTAC case 04OV028, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IV.
Specimen 41d0619e-b299-42e2-ac32-29e784: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fe3276b-7d6d-441e-8a4d-5d9aeb29d5f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1cec1511-2570-4921-bac0-5ceea7 (Blood Derived Normal), aliquot 1cec1511-2570-4921-bac0-5ceea7_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4ac4e51-b537-45e0-9b12-2307653c4693

The open-access MAF lists 72 somatic variants for this specimen: 43 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 24, Frame Shift Del 2, 3'UTR 2, Intron 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1458138648; called by muse, mutect2, varscan2
- AMER1 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 32/860 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1329771600, COSV57667563; called by muse, mutect2
- ANXA7 | c.1105G>T p.A369S (on ENST00000372919 / NM_001320880.2; = p.A347S on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100873428; called by muse, mutect2, varscan2
- CCDC80 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 101/554 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52815719; called by muse, mutect2, varscan2
- DOCK8 | c.4306A>G p.I1436V | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs1275250985; called by muse, mutect2, varscan2
- DPP6 | c.2594A>G p.D865G (on ENST00000377770 / NM_001364500.2; = p.D803G on NM_001936.5) | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100125692; called by muse, mutect2, varscan2
- FGG | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV60195366, COSV60196193; called by muse, mutect2, varscan2
- GRM3 | c.24A>C p.Q8H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.187); catalogued as rs1481766776, COSV64481364; called by muse, varscan2
- HEPACAM2 | c.364G>A p.V122M (on ENST00000394468 / NM_001039372.4; = p.V110M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139218067; called by muse, mutect2, varscan2
- HNF4G | c.203G>A p.R68Q (on ENST00000354370 / NM_001330561.2; = p.R115Q on NM_004133.5) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62967163; called by muse, mutect2, varscan2
- LHPP | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199534407; called by muse, mutect2, varscan2
- MGRN1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs750745824; called by muse, mutect2, varscan2
- MYO5A | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1432906496; called by muse, mutect2, varscan2
- NCOR2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425936508; called by muse, mutect2, varscan2
- NTNG1 | c.1375C>A p.H459N | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV64266759; called by muse, mutect2, varscan2
- PHGDH | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 95/761 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372842833, COSV65571261; called by muse, mutect2, varscan2
- SLX4IP | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV57944672; called by muse, mutect2, varscan2
- TROAP | c.1066C>G p.R356G | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV57745320; called by muse, mutect2
- TTN | c.54709C>T p.P18237S (on ENST00000591111; = p.P10813S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | PolyPhen probably damaging (0.998); catalogued as rs752854931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD35 | c.2009G>C p.R670P | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- BTBD19 | c.709_715del p.E237Rfs*132 | Frame Shift Del (DEL) | VAF 82/422 reads (19%) | called by mutect2, pindel, varscan2
- CCDC136 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC168 | c.10624T>A p.S3542T | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CD6 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CRMP1 | c.1540A>T p.T514S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DLGAP3 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 92/667 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ESCO1 | c.956del p.V319Efs*3 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- GRIA2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.275); called by muse, mutect2
- HSD17B2 | c.478+2T>C p.X160_splice | Splice Site (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- IFT57 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KAT14 | c.2025T>A p.S675R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRRC66 | c.2621G>T p.R874I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NR2E3 | c.350-1G>A p.X117_splice | Splice Site (SNP) | VAF 90/332 reads (27%) | called by muse, varscan2
- ORMDL1 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- PHF2 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLXNC1 | c.999G>C p.M333I | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PTCH2 | c.2683G>C p.E895Q | Missense Mutation (SNP) | VAF 76/504 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- RBM20 | c.1511C>A p.A504D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.187); called by muse, mutect2
- SLC2A9 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2
- SLC38A1 | c.182dup p.K62Efs*3 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, varscan2
- STRIP1 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 82/508 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUN1 | c.1571C>A p.S524* (on ENST00000405266 / NM_001367651.1; = p.S404* on NM_025154.6 and 13 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2, varscan2
- USP40 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA12 | c.1921C>T p.L641= (on ENST00000272895 / NM_173076.3; = p.L323= on NM_015657.3) | Silent (SNP) | VAF 35/304 reads (12%) | catalogued as COSV55971021; called by muse, mutect2, varscan2
- ABCC8 | c.960C>T p.I320= | Silent (SNP) | VAF 150/831 reads (18%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.4197G>A p.T1399= | Silent (SNP) | VAF 92/540 reads (17%) | catalogued as rs567159018; called by muse, mutect2, varscan2
- AGRN | c.3165C>A p.S1055= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as rs753211720; called by muse, mutect2, varscan2
- APC2 | c.2082G>A p.L694= | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.522C>T p.N174= | Silent (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- CFTR | c.231T>C p.F77= | Silent (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- CGN | c.3018C>T p.L1006= | Silent (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- CNR1 | c.636C>T p.I212= | Silent (SNP) | VAF 48/328 reads (15%) | catalogued as rs369882699; called by muse, mutect2, varscan2
- DOCK10 | c.5934C>T p.V1978= | Silent (SNP) | VAF 128/961 reads (13%) | called by muse, mutect2, varscan2
- DST | c.21823C>T p.L7275= (on ENST00000361203 / NM_001374722.1; = p.L4948= on NM_015548.5) | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- EYS | c.6822C>T p.S2274= | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as COSV65539637; called by muse, mutect2, varscan2
- NEU4 | c.540C>T p.R180= (on ENST00000391969 / NM_001167602.3; = p.R192= on NM_080741.4) | Silent (SNP) | VAF 177/1052 reads (17%) | catalogued as rs537386050; called by muse, varscan2
- POGK | c.918C>T p.S306= | Silent (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- RALGPS1 | c.493C>A p.R165= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs746130607, COSV99401536; called by muse, mutect2, varscan2
- RTN4IP1 | c.915C>G p.L305= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- SNX13 | c.1077T>A p.T359= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- TERT | c.2016C>A p.R672= | Silent (SNP) | VAF 112/644 reads (17%) | called by muse, mutect2, varscan2
- TMC5 | c.1908C>T p.A636= (on ENST00000396229 / NM_001105248.1; = p.A390= on NM_024780.5) | Silent (SNP) | VAF 48/181 reads (27%) | catalogued as rs368929801; called by muse, mutect2, varscan2
- TMEM212 | c.285C>G p.A95= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2
- TNRC6B | c.3078T>G p.S1026= (on ENST00000454349 / NM_001162501.2; = p.S973= on NM_015088.3) | Silent (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- WEE2 | c.1566A>T p.S522= | Silent (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- XKR6 | c.453C>A p.L151= | Silent (SNP) | VAF 59/193 reads (31%) | catalogued as rs776631847; called by muse, mutect2, varscan2
- ZNF467 | c.1116G>A p.T372= | Silent (SNP) | VAF 36/224 reads (16%) | catalogued as rs1259454077; called by muse, mutect2, varscan2
- ARHGEF7 | c.1014-1977G>A | Intron (SNP) | VAF 93/363 reads (26%) | called by muse, mutect2, varscan2
- GPER1 | c.*97G>T | 3'UTR (SNP) | VAF 51/324 reads (16%) | called by muse, mutect2, varscan2
- NHSL2 | c.-64G>A | 5'UTR (SNP) | VAF 122/510 reads (24%) | catalogued as rs1276081861; called by muse, mutect2, varscan2
- PLIN1 | c.*1G>T | 3'UTR (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.1301+437G>C | Intron (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
